TCGA case TCGA-EI-6509 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum; Tissue source site: Greater Poland Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/652e503a-1be8-445b-96d6-ff114f911e76

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Poland; Age at index: 53 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma in tubulovillous adenoma (the primary disease): ICD-O-3 morphology code: 8263/3; ICD-10 code: C20; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Rectosigmoid junction; Classification of tumor: primary; Age at diagnosis: 53.8 years (19,666 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N2b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 517 days (1.4 years).
   Pathology details: Circumferential resection margin: 60; Consistent pathology review: Yes; Lymph nodes positive: 7; Lymph nodes tested: 10; Lymphatic invasion present: Yes; Non nodal tumor deposits: No; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Regimen or line of therapy: FOLFOX; Days to treatment start: 395 days (1.1 years); Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Adenocarcinoma in tubulovillous adenoma). Age at diagnosis: 54.1 years (19,756 days); Days to diagnosis: 90 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 127 days; Residual disease: R0; Treatment anatomic sites: Liver.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 90 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 90 days.
- Days to follow up: 250 days; Disease response: Tumor Free.
- Days to follow up: 517 days (1.4 years); Disease response: With Tumor.

Molecular and laboratory tests
- CEA: 2.8 ng/mL.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 82 kg; Height: 178 cm; BMI: 25.9.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EI-6509-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 1; Shortest dimension: 0.6.
  Slide TCGA-EI-6509-01A-01-BS1: Section location: Bottom; Percent tumor cells: 67; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 8; Percent stromal cells: 25.
  Slide TCGA-EI-6509-01A-01-TS1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 40.
- Sample TCGA-EI-6509-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EI-6509-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; CEA level pretreatment: 2.8; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: No.
- Drug treatment, Route of administrations: Route of administration: IV.
- Follow-up form: Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 517 days; disease-specific survival: no event (censored), 517 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 90 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EI-6509-01A-11D-1732-01): tumor purity 0.83, ploidy 2, whole-genome doublings 0.
